MMRF case MMRF_1071 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1778f74c-366b-48bb-9528-9ac10378389f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 42.2 years (15,431 days); ISS stage: II; Days to last known disease status: 1,757 days (4.8 years); Days to last follow up: 1,757 days (4.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 65 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 7 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 102 days; Days to treatment end: 137 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 158 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 973 days (2.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19: M Protein 4.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.729 mg/dL; Immunoglobulin G 61.7 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.68 g/L; Beta 2 Microglobulin 1.68 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 318 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 1.95 mmol/L; Albumin 34 g/L; Total Protein 11.2 g/dL; Glucose 6.22 mmol/L; C-Reactive Protein 0.18 mg/dL.
- Day 64 (ECOG 0): M Protein 0.93 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.516 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.104 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.76 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.62 mmol/L.
- Day 151 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.631 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.553 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.8 g/L; Beta 2 Microglobulin 1.23 µg/mL; Hemoglobin 8.8 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 302 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 46 g/L; Total Protein 7.8 g/dL; Glucose 4.46 mmol/L.
- Day 294 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.962 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.627 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.22 µg/mL; Hemoglobin 8.93 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 5.39 mmol/L.
- Day 378 (ECOG 0): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.59 g/L; Beta 2 Microglobulin 1.34 µg/mL; Hemoglobin 9.24 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 4.46 mmol/L.
- Day 469 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.948 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.493 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 1.18 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.12 mmol/L.
- Day 560 (ECOG 0): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.689 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.93 g/L; Beta 2 Microglobulin 1.48 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 8 g/dL; Glucose 5.34 mmol/L.
- Day 665 (ECOG 0): M Protein 0.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.764 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.86 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 5.17 mmol/L.
- Day 756 (ECOG 0): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.816 mg/dL; Immunoglobulin G 16.4 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.91 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 4.79 mmol/L.
- Day 840 (ECOG 0): M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.495 mg/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.77 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 8.1 g/dL; Glucose 4.62 mmol/L.
- Day 924 (ECOG 0): M Protein 1.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.493 mg/dL; Immunoglobulin G 18.9 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.88 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.9 g/dL; Glucose 5.78 mmol/L.
- Day 973 (ECOG 0): M Protein 1.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.564 mg/dL; Immunoglobulin G 21.7 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.87 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 309 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.6 mmol/L; Albumin 45 g/L; Total Protein 8.3 g/dL; Glucose 4.68 mmol/L.
- Day 1,060 (ECOG 0): M Protein 0.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 1.8 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.27 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 1,144 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 5.06 mmol/L.
- Day 1,225 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 0.76 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 4.57 mmol/L.
- Day 1,316 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 9.61 g/L; Immunoglobulin A 2.51 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.58 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.62 mmol/L.
- Day 1,400 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 9.78 g/L; Immunoglobulin A 1.93 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 4.68 mmol/L.
- Day 1,484 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.29 mmol/L.
- Day 1,568 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 2.24 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.64 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.57 mmol/L.
- Day 1,652 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.139 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.513 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.53 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 1,757 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.757 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Immunoglobulin G 7.58 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.81 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.5 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -19: Weight: 73 kg; Height: 158 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1071_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 973 days (2.7 years).
- Sample MMRF_1071_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 973 days (2.7 years).
